MMRF case MMRF_1407 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e7f28687-fdb2-4dc9-9461-3a297f0860bd

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.7 years (26,206 days); ISS stage: I; Days to last known disease status: 1,427 days (3.9 years); Days to last follow up: 1,427 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 78 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 201 days; Days to treatment end: 271 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 201 days; Days to treatment end: 277 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 286 days; Days to treatment end: 1,021 days (2.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,427.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.62 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 398 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.65 mmol/L; Albumin 49 g/L; Total Protein 7.2 g/dL; Glucose 7.37 mmol/L; C-Reactive Protein 1.08 mg/dL.
- Day 90: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 4 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 10.1 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 174 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 5.53 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 4.07 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 4.86 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.92 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.5 g/dL; Glucose 12.9 mmol/L.
- Day 356 (ECOG 0): Hemoglobin 8.18 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 8.58 mmol/L.
- Day 440 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 9.36 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.23 mmol/L.
- Day 531 (ECOG 1): Hemoglobin 8 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Glucose 6.27 mmol/L.
- Day 615 (ECOG 0): Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 699 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.85 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.12 mmol/L.
- Day 811 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 8.98 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 7.32 mmol/L.
- Day 895 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 8.84 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.66 mmol/L.
- Day 951 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.19 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6 mmol/L.
- Day 1,077 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 7.21 mmol/L.
- Day 1,161 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 7.66 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 7.76 mmol/L.
- Day 1,244 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 8.09 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 6.71 mmol/L.
- Day 1,338 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.16 mmol/L.
- Day 1,426 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 6.57 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -12: Weight: 71 kg; Height: 167 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1407_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1407_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
- Sample MMRF_1407_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 174 days.
